Gene-level copy-number profile of tumor specimen ALCH-B0CS-TTP1-A from ALCHEMIST case ALCH-B0CS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.8 years (24,409 days).
Specimen ALCH-B0CS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 82556f0f-53c2-4735-9720-760d8798e0f4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B0CS-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/4507528b-6007-46d8-8190-f4d6359fc9fd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 87; copy number 1: 4,558; copy number 2: 53,848; copy number 3: 391; copy number 4: 26.

Homozygous deletions (total copy number 0; autosomes only): 79 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:130,139,287–130,190,729, 3 genes (within-gene range 0–2): CCDC74B, SMPD4, MZT2B.
- chr2:232,520,388–232,536,667, 2 genes: PRSS56, CHRND.
- chr2:238,100,340–238,152,947, 2 genes (within-gene range 0–2): ESPNL, KLHL30.
- chr2:241,776,822–241,873,823, 7 genes: GAL3ST2, AC131097.1, AC131097.2, NEU4, AC131097.3, PDCD1, RTP5.
- chr2:241,893,988–241,902,551, 1 gene (within-gene range 0–2): FAM240C.
- chr3:126,988,594–127,037,392, 1 gene: PLXNA1.
- chr4:118,635,970–118,640,858, 2 genes: CICP16, SEPTIN14P4.
- chr7:1,530,702–1,560,821, 2 genes: MAFK, TMEM184A.
- chr7:76,510,525–76,522,074, 2 genes: UPK3B, AC004980.4.
- chr9:123,356,170–123,380,324, 1 gene (within-gene range 0–3): CRB2.
- chr11:1,389,899–1,462,689, 1 gene: BRSK2.
- chr12:34,249,481–34,249,958, 1 gene: AK6P1.
- chr12:132,565,071–132,610,582, 4 genes (within-gene range 0–1): AC131212.2, MIR6763, AC131212.1, LRCOL1.
- chr15:25,172,635–25,225,284, 29 genes (within-gene range 0–2): SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr16:88,382,959–88,440,757, 1 gene: ZNF469.
- chr17:81,976,807–82,039,380, 7 genes: ASPSCR1, CENPX, LRRC45, RAC3, DCXR, AC137723.1, DCXR-DT.
- chr17:82,078,338–82,098,294, 1 gene: FASN.
- chr18:79,395,856–79,529,325, 6 genes (within-gene range 0–1): NFATC1, AC018445.3, AC018445.5, AC018445.1, AC018445.4, AC018445.2.
- chr22:17,764,180–17,779,481, 2 genes (within-gene range 0–2): MIR3198-1, LINC00528.
- chr22:18,951,934–18,959,512, 1 gene: AC007326.2.
- chr22:29,705,256–29,731,833, 3 genes (within-gene range 0–2): AC004882.1, AC004882.2, CABP7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,714. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
